Somatic mutation profile of tumor specimen HCM-CSHL-0186-C25-01A (aliquot HCM-CSHL-0186-C25-01A-21D-A79L-36) from HCMI case HCM-CSHL-0186-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 74.2 years (27,102 days).
Specimen HCM-CSHL-0186-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ade8a672-9ef6-45b1-88d2-791ba5a181f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0186-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0186-C25-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5a64d70-0f7b-48e4-b996-93cd0afc02ec

The open-access MAF lists 49 somatic variants for this specimen: 38 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 10, Frame Shift Ins 2, 5'UTR 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 27/204 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 57/307 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1057520000, COSV52677206, COSV52707835, COSV52811105; ClinVar: likely pathogenic / uncertain significance; called by mutect2, varscan2
- CCDC141 | c.4426G>A p.A1476T | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as rs760885419, COSV55384880; called by muse, mutect2, varscan2
- CCDC166 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 165/750 reads (22%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.16); catalogued as rs1199782513; called by muse, mutect2, varscan2
- CDKN2A | c.130dup p.Y44Lfs*76 | Frame Shift Ins (INS) | VAF 54/366 reads (15%) | catalogued as COSV58682773, COSV58689669, COSV58711803, COSV58713131; called by mutect2, pindel, varscan2
- CHAF1A | c.2465C>T p.P822L | Missense Mutation (SNP) | VAF 64/402 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); catalogued as rs150699024; called by muse, mutect2, varscan2
- EPB42 | c.89G>A p.R30H (on ENST00000441366 / NM_001114134.2; = p.R60H on NM_000119.3) | Missense Mutation (SNP) | VAF 48/342 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as rs1329445100, COSV55751390; called by muse, mutect2, varscan2
- FOXG1 | c.1008C>G p.S336R | Missense Mutation (SNP) | VAF 88/537 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.188); catalogued as COSV57399167; called by muse, mutect2, varscan2
- HS3ST2 | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 68/421 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564701428, COSV54457820; called by muse, mutect2, varscan2
- MVP | c.1972G>A p.V658I | Missense Mutation (SNP) | VAF 69/429 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as rs986124471, COSV62423538; called by muse, mutect2, varscan2
- NIPAL4 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 21/302 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs372087764; called by muse, mutect2
- PLA2G4D | c.2432C>T p.A811V | Missense Mutation (SNP) | VAF 46/275 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs370314190; called by muse, mutect2, varscan2
- PLK5 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 89/609 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs943611813; called by muse, mutect2, varscan2
- PTP4A1 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs755475012; called by muse, mutect2, varscan2
- RET | c.1538C>T p.A513V | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs149238501, COSV60688566, COSV60711451; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFAT | c.3328G>A p.A1110T | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as rs759170959, COSV64748576; called by muse, mutect2
- ZFP64 | c.1921G>A p.A641T | Missense Mutation (SNP) | VAF 51/377 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as rs1568679651, COSV53800118; called by muse, mutect2, varscan2
- ZNF420 | c.1783G>A p.A595T | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.114); catalogued as rs771142519; called by muse, mutect2, varscan2
- AATF | c.1007G>A p.R336K | Missense Mutation (SNP) | VAF 39/413 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2
- ATP2B1 | c.1197del p.Q400Rfs*18 | Frame Shift Del (DEL) | VAF 49/209 reads (23%) | called by mutect2, pindel, varscan2
- BARHL2 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 85/605 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.058); called by muse, varscan2
- C11orf54 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 41/254 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- INSYN2B | c.1459C>T p.H487Y | Missense Mutation (SNP) | VAF 34/443 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2
- KCNJ15 | c.110A>G p.N37S | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- KDM6A | c.3840T>A p.N1280K | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.74T>C p.V25A | Missense Mutation (SNP) | VAF 52/487 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- MMP28 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); called by muse, mutect2
- MMRN2 | c.778A>T p.R260* | Nonsense Mutation (SNP) | VAF 44/306 reads (14%) | called by muse, mutect2, varscan2
- MYO18B | c.5850G>A p.M1950I | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- NDUFB8 | c.91C>G p.H31D | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- SCAF8 | c.3088C>A p.P1030T | Missense Mutation (SNP) | VAF 34/248 reads (14%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.018); called by muse, varscan2
- SDHAF2 | c.479A>G p.Y160C | Missense Mutation (SNP) | VAF 59/337 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SEC24A | c.566G>A p.G189D | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SHANK3 | c.709C>T p.L237F | Missense Mutation (SNP) | VAF 46/355 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPEG | c.7681C>G p.P2561A | Missense Mutation (SNP) | VAF 73/510 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- TAF11L8 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 13/651 reads (2%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- TGFBR2 | c.1223dup p.S409Vfs*4 | Frame Shift Ins (INS) | VAF 25/221 reads (11%) | called by mutect2, pindel, varscan2
- VWA5B2 | c.3536G>T p.R1179L | Missense Mutation (SNP) | VAF 84/590 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, varscan2
- ADCY5 | c.3147C>T p.A1049= | Silent (SNP) | VAF 97/480 reads (20%) | catalogued as rs754369625, COSV59194567; called by muse, mutect2, varscan2
- CELSR2 | c.7329C>A p.A2443= | Silent (SNP) | VAF 13/379 reads (3%) | called by muse, mutect2
- GRM8 | c.2136C>T p.V712= | Silent (SNP) | VAF 26/262 reads (10%) | called by muse, mutect2, varscan2
- NDUFAF6 | c.90C>T p.Y30= | Silent (SNP) | VAF 133/636 reads (21%) | called by muse, mutect2, varscan2
- SEMA6B | c.1512C>T p.D504= | Silent (SNP) | VAF 28/582 reads (5%) | catalogued as rs751082219, COSV100014840; called by muse, mutect2
- SHANK1 | c.5190C>G p.A1730= | Silent (SNP) | VAF 51/441 reads (12%) | called by muse, mutect2, varscan2
- SMC2 | c.3593A>G p.*1198= | Silent (SNP) | VAF 13/105 reads (12%) | called by muse, mutect2, varscan2
- SMPD4 | c.1398G>A p.S466= (on ENST00000409031 / NM_017951.4; = p.S437= on NM_017751.4) | Silent (SNP) | VAF 59/392 reads (15%) | catalogued as rs1558742121, COSV60079749; called by muse, mutect2, varscan2
- USH2A | c.8643A>T p.S2881= | Silent (SNP) | VAF 53/245 reads (22%) | called by muse, mutect2
- XPR1 | c.330C>T p.R110= | Silent (SNP) | VAF 53/331 reads (16%) | catalogued as rs1394123540, COSV62561654; called by muse, mutect2, varscan2
- PREP | c.-115C>T | 5'UTR (SNP) | VAF 38/218 reads (17%) | catalogued as rs766719326; called by muse, mutect2, varscan2
